Somatic mutation profile of tumor specimen 0DQ55P from CCDI case PBCEGP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.8 years (3,951 days).
Specimen 0DQ55P: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53a3e217-0798-4243-b7de-2dc16fc66268.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ55T (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9f66e8a-81e1-4085-84fd-d81a448bd77d

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 2, In Frame Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1914_1916dup p.T639dup (on ENST00000288602 / NM_001374244.1; = p.T599dup on NM_004333.6 and 3 other RefSeq transcripts) | In Frame Ins (INS) | VAF 321/960 reads (33%) | catalogued as rs727502902; ClinVar: pathogenic; called by mutect2, varscan2
- CREBBP | c.3504del p.R1169Afs*81 | Frame Shift Del (DEL) | VAF 114/398 reads (29%) | called by mutect2, varscan2
- SPATA13 | c.1741G>A p.A581T | Missense Mutation (SNP) | VAF 168/645 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- TIGD6 | c.428G>C p.S143T | Missense Mutation (SNP) | VAF 110/723 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ZC3H13 | c.1519T>G p.Y507D | Missense Mutation (SNP) | VAF 148/492 reads (30%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- DDIT4L | c.*80G>C | 3'UTR (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- SGPP1 | c.*41T>A | 3'UTR (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
